Somatic mutation profile of tumor specimen BA2124D (aliquot aq-BA2124D) from BEATAML1.0 case 2310, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.2 years (24,533 days).
Specimen BA2124D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df814e3f-256f-46af-84c3-d307e16685c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2929D (Solid Tissue Normal), aliquot aq-BA2929D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca6afb28-ee18-4059-a15a-70a1a8a1a68b

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- ACOD1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs772797580, COSV66291392; called by muse, varscan2
- AHNAK | c.10052G>A p.R3351H | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs112103583; called by muse, mutect2, varscan2
- CFAP70 | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV60281441; called by muse, mutect2, varscan2
- FAM110B | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs781565308; called by muse, mutect2, varscan2
- PKD1L2 | c.2192C>T p.T731I | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs774258611; called by muse, varscan2
- RPL26 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs748748690; called by muse, mutect2, varscan2
- ZRSR2 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 43/45 reads (96%) | catalogued as rs754175667, COSV57066630; called by muse, mutect2, varscan2
- AC004997.1 | c.751+5G>A | Splice Region (SNP) | VAF 45/69 reads (65%) | called by muse, mutect2, varscan2
- APBB3 | c.730C>T p.H244Y (on ENST00000357560 / NM_133173.2; = p.H251Y on NM_006051.3) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, varscan2
- CHD1 | c.3731C>T p.T1244I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HECW2 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ITIH3 | c.2296G>A p.V766I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by mutect2, varscan2
- LOXHD1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4A5 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SAMD7 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SETD2 | c.4219del p.R1407Gfs*5 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | called by mutect2, pindel, varscan2
- ZNF394 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ADGRV1 | c.18348C>T p.S6116= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs774124713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.5739A>G p.L1913= | Silent (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- C10orf67 | c.1521G>A p.K507= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as rs1192079420; called by muse, mutect2, varscan2
- PCDHA10 | c.1446C>T p.D482= | Silent (SNP) | VAF 8/241 reads (3%) | catalogued as COSV56541619; called by muse, mutect2
- PCDHA6 | c.654C>A p.G218= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SYNE4 | c.333G>T p.L111= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- AC084879.1 | n.1200C>T | RNA (SNP) | VAF 81/173 reads (47%) | called by muse, mutect2, varscan2
